Gene-level copy-number profile of tumor specimen TARGET-40-PATAWV-01A from TARGET case TARGET-40-PATAWV, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.5 years (5,667 days).
Specimen TARGET-40-PATAWV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.e78d00de-99f8-5d7e-ad68-32f1d87dd9d9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PATAWV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 465 have no estimate.
https://portal.gdc.cancer.gov/files/0bbdef5f-4022-49ec-b5f5-7294570cc384

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 2,044; copy number 2: 2,664; copy number 3: 12,636; copy number 4: 17,610; copy number 5: 13,011; copy number 6: 6,734; copy number 7: 1,831; copy number 8: 721; copy number 9: 1,817; copy number 10: 357; copy number 11: 44; copy number 12: 25; copy number 13: 185; copy number 14: 42; copy number 15: 143; copy number 16: 6; copy number 17: 112; copy number 18: 46; copy number 19: 109.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr2:227,870,083–228,379,773, 7 genes: TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P, SNF8P1, AC009410.1.
- chr3:116,850,277–116,965,227, 4 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr5:165,782,805–167,168,401, 8 genes: AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,886 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,907,956–91,024,804, 636 genes, copy number 12–19 (within-gene range 3–19) (broad region; genes not listed).
- chr1:92,189,237–93,847,150, 40 genes, copy number 9–13 (within-gene range 5–13): AC104836.1, C1orf146, ACTBP12, GLMN, RPAP2, RN7SL824P, GFI1, EVI5, AL354890.1, HMGB3P9, RNU4-59P, AC104332.1, H3P3, CCNJP2, RPL5, DIPK1A, SNORD21, SNORA66, AL162740.1, AL449283.1, RNU6-970P, RN7SL692P, AC093577.1, RNU6-210P, RN7SKP123, Y_RNA, MTF2, TMED5, CCDC18, AC126124.2, AC126124.1, CCDC18-AS1, AL139421.1, DR1, AL137159.1, Y_RNA, FNBP1L, RNA5SP53, BCAR3, BCAR3-AS1.
- chr1:107,571,161–110,209,987, 85 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr1:111,739,579–111,998,842, 7 genes, copy number 9: INKA2-AS1, AL049557.1, DDX20, KCND3, KCND3-IT1, KCND3-AS1, LINC01750.
- chr1:199,876,978–200,177,420, 8 genes, copy number 14: AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1.
- chr2:183,253,652–183,495,501, 2 genes, copy number 9 (within-gene range 4–9): AC021851.2, LIN28AP1.
- chr4:77,157,207–77,433,388, 4 genes, copy number 9 (within-gene range 5–9): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr4:81,164,922–86,892,422, 79 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr5:179,492,076–179,527,513, 4 genes, copy number 13: U4, AC136628.4, AC136628.2, AC136628.3.
- chr6:21,233,168–21,271,132, 1 gene, copy number 9: AL451080.1.
- chr6:104,487,095–105,588,802, 17 genes, copy number 9 (within-gene range 4–9): AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1.
- chr6:170,254,334–170,419,325, 8 genes, copy number 11: AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1.
- chr8:33,859,480–33,860,223, 1 gene, copy number 9: AF279873.2.
- chr8:49,906,863–50,796,692, 2 genes, copy number 12 (within-gene range 6–12): AC023762.1, SNTG1.
- chr8:52,110,839–52,460,959, 1 gene, copy number 9 (within-gene range 6–9): ST18.
- chr8:52,294,455–139,704,109, 1,236 genes, copy number 9–10 (within-gene range 9–12) (broad region; genes not listed).
- chr13:94,651,397–98,752,672, 64 genes, copy number 9–11 (broad region; genes not listed).
- chr13:113,105,788–114,337,626, 48 genes, copy number 10: F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:18,333,726–19,957,996, 83 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr15:20,940,380–21,260,147, 14 genes, copy number 9: LINC01193, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16, NBEAP4.
- chr17:10,258,762–21,002,276, 414 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr17:20,999,747–21,000,323, 1 gene, copy number 9: AC087393.2.
- chr18:31,829,197–32,470,882, 24 genes, copy number 10: TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.
- chr18:32,511,663–32,566,634, 2 genes, copy number 10: WBP11P1, AC009835.1.
- chr18:36,297,714–36,829,216, 3 genes, copy number 10 (within-gene range 3–10): FHOD3, AC055840.1, TPGS2.
- chr22:39,743,044–42,343,616, 99 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr22:43,400,331–43,513,727, 3 genes, copy number 9: LINC01639, MPPED1, BX546033.1.

Autosomal genes at a single copy (total copy number 1): 300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
